Somatic mutation profile of tumor specimen TCGA-12-0662-01A (aliquot TCGA-12-0662-01A-01W-0348-08) from TCGA case TCGA-12-0662, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.2 years (18,717 days).
Specimen TCGA-12-0662-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5ec3704-fb9d-48fb-9ba0-22e502771174.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0662-10A (Blood Derived Normal), aliquot TCGA-12-0662-10A-01W-0348-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6169a6ba-4f56-427e-845b-b3ced5ae150d

The open-access MAF lists 33 somatic variants for this specimen: 28 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Splice Site 3, RNA 2, Frame Shift Ins 2, Silent 2, Frame Shift Del 1, Intron 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TNNI3 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs104894724, CM030285, CM971498, COSV52572598; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 60/210 reads (29%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.97-2A>G p.X33_splice | Splice Site (SNP) | VAF 44/237 reads (19%) | hotspot (GDC flag); catalogued as rs879254212, COSV52678373, COSV52848662, COSV53375861, COSV53887648; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADD2 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV100034764; called by muse, mutect2, varscan2
- ARHGEF4 | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV100387615; called by muse, mutect2, varscan2
- ATP10B | c.851G>A p.G284D | Missense Mutation (SNP) | VAF 101/308 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100469076; called by muse, mutect2, varscan2
- COL14A1 | c.3512A>G p.D1171G | Missense Mutation (SNP) | VAF 126/433 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99918074; called by muse, mutect2, varscan2
- CPA1 | c.987+1G>A p.X329_splice | Splice Site (SNP) | VAF 29/107 reads (27%) | catalogued as COSV99163218; called by muse, mutect2, varscan2
- DHX16 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as rs747886418, COSV64581439; called by muse, mutect2, varscan2
- ENC1 | c.979C>A p.P327T | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100187893; called by muse, mutect2
- ESPL1 | c.5462G>A p.R1821H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs1037657641, COSV99228913; called by muse, mutect2, varscan2
- GALNT6 | c.86G>A p.R29K | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as rs951799213, COSV100695302; called by muse, mutect2
- ITCH | c.2485C>T p.Q829* (on ENST00000262650 / NM_001257137.3; = p.Q788* on NM_031483.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/410 reads (4%) | catalogued as COSV99392021; called by muse, mutect2
- JADE2 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50914262; called by muse, mutect2, varscan2
- LPAR4 | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 116/165 reads (70%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV101425075; called by muse, mutect2, varscan2
- MPIG6B | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV101008027; called by muse, mutect2, varscan2
- PLD2 | c.2075C>G p.S692C | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV99562044; called by muse, mutect2
- PLK3 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV100221009; called by muse, mutect2
- QSER1 | c.4520A>G p.E1507G (on ENST00000399302; = p.E1636G on NM_001076786.3) | Missense Mutation (SNP) | VAF 40/385 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV101234655, COSV67901791; called by muse, mutect2, varscan2
- RBM26 | c.1903T>C p.S635P (on ENST00000438737 / NM_001366735.2; = p.S632P on NM_022118.5) | Missense Mutation (SNP) | VAF 224/437 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); catalogued as COSV99935815; called by muse, mutect2, varscan2
- RHBDD2 | c.738-1G>A p.X246_splice | Splice Site (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99138166; called by muse, mutect2, varscan2
- RHPN2 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 92/221 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99576878, COSV99577050; called by muse, mutect2, varscan2
- SLC2A12 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 236/729 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99259640; called by muse, mutect2, varscan2
- UGT2B15 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 528/2791 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV100592222; called by muse, mutect2, varscan2
- ZNF44 | c.1800G>T p.R600S (on ENST00000356109 / NM_001164276.2; = p.R552S on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as rs753031947, COSV100633476; called by muse, mutect2, varscan2
- SNX16 | c.576del p.Q193Kfs*3 | Frame Shift Del (DEL) | VAF 68/258 reads (26%) | called by mutect2, pindel, varscan2
- STAU2 | c.870dup p.R291Tfs*3 (on ENST00000524300 / NM_001164380.2; = p.R259Tfs*3 on NM_014393.2) | Frame Shift Ins (INS) | VAF 23/82 reads (28%) | called by mutect2, pindel, varscan2
- TNR | c.637dup p.V213Gfs*10 | Frame Shift Ins (INS) | VAF 10/102 reads (10%) | called by mutect2, pindel
- ITGB2 | c.891C>T p.N297= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs770882421, COSV56612262, COSV56615191; called by muse, mutect2, varscan2
- RBM19 | c.2505G>A p.L835= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs749292797, COSV99925532; called by muse, mutect2, varscan2
- DIABLO | c.-37+1329A>C | Intron (SNP) | VAF 28/92 reads (30%) | catalogued as rs201330335, COSV99928024; called by muse, mutect2, varscan2
- FOLH1B | n.1058A>G | RNA (SNP) | VAF 149/497 reads (30%) | called by muse, mutect2, varscan2
- RPS26P15 | n.103G>A | RNA (SNP) | VAF 20/167 reads (12%) | called by muse, mutect2, varscan2
